Somatic mutation profile of tumor specimen TCGA-DX-AB2Q-01A (aliquot TCGA-DX-AB2Q-01A-11D-A38Z-09) from TCGA case TCGA-DX-AB2Q, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 65.0 years (23,748 days).
Specimen TCGA-DX-AB2Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5656b7ff-52c0-439c-bb5c-13e4913066e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2Q-10A (Blood Derived Normal), aliquot TCGA-DX-AB2Q-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4606fa3b-f224-4192-a87b-18c5fb17bd44

The open-access MAF lists 78 somatic variants for this specimen: 62 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 52, Silent 16, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM28 | c.971A>T p.Q324L | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV99737682; called by muse, mutect2
- ADGRE2 | c.573C>A p.C191* | Nonsense Mutation (SNP) | VAF 39/69 reads (57%) | catalogued as COSV100215673; called by muse, mutect2, varscan2
- ADGRV1 | c.8526A>G p.I2842M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV101315474; called by muse, mutect2, varscan2
- ANKRD11 | c.5588A>G p.D1863G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99968228; called by muse, mutect2, varscan2
- APMAP | c.1020G>A p.W340* | Nonsense Mutation (SNP) | VAF 8/67 reads (12%) | catalogued as rs1362330242, COSV99468152; called by muse, mutect2, varscan2
- CCDC88C | c.5977G>A p.G1993S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs201422981, COSV100484654; called by muse, mutect2, varscan2
- CDK11B | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.052); catalogued as rs747942866, COSV100477241; called by muse, mutect2, varscan2
- CHST14 | c.953A>T p.H318L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100086885, COSV60379587; called by muse, mutect2, varscan2
- CNTRL | c.3876G>A p.M1292I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1163204147, COSV99441078; called by muse, mutect2, varscan2
- CROCC | c.1786A>C p.S596R | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as COSV100978049; called by muse, mutect2
- DAPK1 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.528); catalogued as rs1412477610, COSV100800958; called by muse, mutect2, varscan2
- DGKB | c.1379A>T p.Q460L | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV99336311; called by muse, mutect2
- DLGAP2 | c.2778G>C p.W926C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101421013; called by muse, mutect2, varscan2
- DNAAF3 | c.803T>C p.V268A (on ENST00000524407 / NM_001256715.2; = p.V315A on NM_178837.4) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100787841; called by muse, mutect2, varscan2
- EP300 | c.397T>G p.S133A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.082); catalogued as COSV99607268; called by mutect2, varscan2
- EPHA3 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100342701, COSV100350092; called by muse, mutect2, varscan2
- FASN | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV100147288; called by muse, mutect2, varscan2
- FBN1 | c.6380-1G>C p.X2127_splice | Splice Site (SNP) | VAF 29/88 reads (33%) | catalogued as COSV100353988; called by muse, mutect2, varscan2
- GLA | c.794del p.P265Qfs*4 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | catalogued as CM051528, CM960770; called by mutect2, pindel, varscan2
- GOLT1B | c.252G>C p.L84F | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV57554397; called by muse, mutect2, varscan2
- GTF2B | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100980491; called by muse, mutect2, varscan2
- HSP90AA1 | c.1529G>T p.R510L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as COSV99355009; called by muse, mutect2, varscan2
- KIR3DL1 | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV58492340; called by muse, mutect2, varscan2
- LARP6 | c.872T>C p.I291T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1250776733, COSV100150675; called by muse, mutect2, varscan2
- LONRF2 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV101110840; called by muse, mutect2
- LRG1 | c.703C>T p.Q235* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100014632; called by muse, mutect2, varscan2
- LTK | c.1997G>A p.G666E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs755225073, COSV99540554; called by muse, mutect2, varscan2
- MEOX2 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as rs1488119800, COSV100011926; called by muse, mutect2, varscan2
- MYH7B | c.5322G>C p.Q1774H | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV99327763; called by muse, mutect2, varscan2
- MYT1L | c.1556A>G p.Y519C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101218698, COSV101219938; called by muse, mutect2, varscan2
- NDST4 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52137628; called by muse, mutect2, varscan2
- OR1G1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV100187496; called by muse, mutect2, varscan2
- OR2A25 | c.136G>T p.G46W | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV101376328; called by muse, mutect2, varscan2
- OR2H1 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101009779; called by muse, mutect2, varscan2
- OR51D1 | c.9G>T p.K3N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.282); catalogued as COSV100712344; called by muse, mutect2, varscan2
- OR51F1 | c.739T>C p.F247L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.186); catalogued as COSV100598638; called by mutect2, varscan2
- OR52B2 | c.729T>G p.C243W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101603924; called by muse, mutect2, varscan2
- PARD6B | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.477); catalogued as COSV100859861; called by muse, mutect2, varscan2
- PCDHB15 | c.421A>G p.K141E | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.189); catalogued as COSV99178816; called by muse, mutect2, varscan2
- PIK3C2G | c.2842A>G p.I948V (on ENST00000676171; = p.I907V on NM_004570.5) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.561); catalogued as COSV99849384; called by muse, mutect2, varscan2
- PKD1 | c.7067T>G p.V2356G | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99237117; called by muse, mutect2, varscan2
- PKD1L1 | c.4709G>C p.R1570T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs1188101333, COSV99218355; called by muse, mutect2, varscan2
- PPFIA1 | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99556785; called by muse, mutect2, varscan2
- PPP1R12A | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.453); catalogued as COSV54105466; called by muse, mutect2, varscan2
- PTPRU | c.2374A>G p.T792A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs527888616, COSV100111501; called by mutect2, varscan2
- RANBP2 | c.3402C>A p.F1134L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV99311224, COSV99313600; called by muse, mutect2
- SCUBE1 | c.2599A>T p.T867S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100682799; called by muse, mutect2, varscan2
- SGIP1 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99390423; called by muse, mutect2, varscan2
- SLC4A7 | c.2372A>G p.N791S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200933810, COSV99839146; called by muse, mutect2, varscan2
- SMC5 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1458362269, COSV100746952; called by muse, mutect2, varscan2
- SPAG17 | c.6409G>A p.E2137K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100307863; called by muse, mutect2, varscan2
- SPIN4 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV100633299; called by muse, mutect2, varscan2
- TBL3 | c.1399A>T p.I467F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100224681; called by muse, mutect2, varscan2
- TMEM217 | c.360C>A p.D120E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV100362454; called by muse, mutect2, varscan2
- TNRC6C | c.1934C>A p.T645K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100049439; called by muse, mutect2, varscan2
- TNXB | c.2740C>T p.R914W | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs542966732, COSV100925792; called by muse, mutect2, varscan2
- TRIM38 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100837529; called by muse, mutect2, varscan2
- TSHZ2 | c.82_84del p.K28del | In Frame Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs772403150; called by mutect2, pindel, varscan2
- WNK1 | c.6709G>C p.A2237P (on ENST00000315939 / NM_018979.4; = p.A1989P on NM_014823.3) | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99942395; called by muse, mutect2
- MYH15 | c.1856_1862dup p.Q622Cfs*15 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | called by mutect2, varscan2
- SPATA25 | c.600_613del p.W200Cfs*14 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- ZBED4 | c.1643dup p.N548Kfs*9 | Frame Shift Ins (INS) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- AGAP4 | c.273G>A p.Q91= | Silent (SNP) | VAF 14/440 reads (3%) | called by muse, mutect2
- AKAP9 | c.3471G>A p.K1157= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as COSV100661887, COSV100662134; called by muse, mutect2, varscan2
- ALG1L | c.36G>T p.G12= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100444688, COSV61075958; called by muse, mutect2, varscan2
- ARSD | c.1248C>T p.D416= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs776155435, COSV99471944; called by muse, mutect2, varscan2
- ASIC5 | c.624T>C p.F208= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV101539712; called by muse, mutect2, varscan2
- CDK10 | c.858G>A p.K286= (on ENST00000353379 / NM_052988.5; = p.K215= on NM_052987.4) | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1039975251, COSV99232063; called by muse, varscan2
- EMX1 | c.828G>A p.T276= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs1235249095, COSV50689617; called by muse, mutect2, varscan2
- FBXO42 | c.1062C>T p.F354= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100981627; called by muse, mutect2, varscan2
- GRID1 | c.1863C>T p.G621= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs770151501, COSV60018453; called by muse, mutect2, varscan2
- ISLR2 | c.666G>A p.V222= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100679392; called by muse, mutect2, varscan2
- KCNK13 | c.990C>T p.D330= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as rs139112374; called by muse, mutect2, varscan2
- MKI67 | c.8985C>G p.P2995= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100896153; called by muse, mutect2, varscan2
- NCALD | c.336A>G p.G112= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99636661; called by muse, mutect2, varscan2
- PCDHB14 | c.2184C>T p.P728= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs782505780, COSV99505523; called by mutect2, varscan2
- PLEKHA2 | c.1137C>T p.F379= | Silent (SNP) | VAF 184/281 reads (65%) | catalogued as COSV100205576; called by muse, mutect2, varscan2
- TEX11 | c.1800G>A p.K600= (on ENST00000344304; = p.K585= on NM_031276.3) | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV100721316; called by muse, mutect2, varscan2
